Somatic mutation profile of tumor specimen 0DU9N2 from CCDI case PBCKMY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.5 years (4,214 days).
Specimen 0DU9N2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac3dccb5-5528-46b6-889d-99a0592ba6b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f167e783-65db-4ece-b193-93656e50ed60

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, Nonsense Mutation 2, Silent 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 176/513 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- SLC12A6 | c.2809C>T p.R937* (on ENST00000354181 / NM_001365088.1; = p.R886* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 130/334 reads (39%) | catalogued as rs1057516262; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 306/706 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GBP5 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 156/380 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756146590, COSV58592319; called by muse, varscan2
- ITGA2B | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 150/362 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV52232323; called by muse, varscan2
- MAMDC4 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs771232486; called by muse, varscan2
- NOD1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 179/414 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs763816357, COSV56112884; called by muse, varscan2
- PHF12 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 320/706 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs751874937; called by muse, varscan2
- PHOSPHO1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs772698351, COSV99865549; called by muse, varscan2
- RTRAF | c.531+5G>A | Splice Region (SNP) | VAF 146/354 reads (41%) | catalogued as rs762723183; called by muse, varscan2
- SLC10A2 | c.941G>A p.C314Y | Missense Mutation (SNP) | VAF 184/454 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1465028654; called by muse, varscan2
- ARID2 | c.5284G>T p.G1762* | Nonsense Mutation (SNP) | VAF 121/260 reads (47%) | called by muse, varscan2
- DTNB | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- GREB1L | c.5462T>C p.I1821T | Missense Mutation (SNP) | VAF 168/376 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, varscan2
- OPN1LW | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 542/1528 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SYPL1 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 158/400 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GRIK5 | c.366C>T p.P122= | Silent (SNP) | VAF 254/604 reads (42%) | catalogued as rs772036723, COSV53476686; called by muse, varscan2
- PPP4R4 | c.2274C>T p.T758= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as COSV58553067; called by muse, varscan2
- ABI3BP | c.1576+9168A>C | Intron (SNP) | VAF 56/118 reads (47%) | called by muse, varscan2
- GRM2 | c.1288+853G>A | Intron (SNP) | VAF 76/175 reads (43%) | called by muse, varscan2
- TTLL10 | c.*22G>A | 3'UTR (SNP) | VAF 40/76 reads (53%) | catalogued as rs767613194; called by muse, varscan2
